Gene-level copy-number profile of tumor specimen TCGA-22-5492-01A from TCGA case TCGA-22-5492, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 73.5 years (26,838 days).
Specimen TCGA-22-5492-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.81057f6a-88e7-4495-a3c8-50337b07430b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-22-5492-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b144c870-9078-4921-bcf2-f10c5d62ec1a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 13,054; copy number 2: 39,409; copy number 3: 6,258; copy number 4: 174; copy number 5: 243; copy number 6: 441; copy number 7: 44; copy number 9: 144; copy number 13: 32; copy number 24: 20.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-22-5492-01A-01D-1631-01): tumor purity 0.56, ploidy 1.96, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 924 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:55,231,903–64,616,556, 160 genes, copy number 7–9 (broad region; genes not listed).
- chr2:64,644,612–64,666,064, 2 genes, copy number 9: AC007365.1, RPS10P9.
- chr2:96,836,611–98,618,515, 52 genes, copy number 13–24 (within-gene range 3–24): ANKRD39, SEMA4C, FAM178B, AC092636.1, Metazoa_SRP, RNA5SP101, AC079395.3, AC079395.2, AC079395.1, TRIM43CP, AC018892.1, AC018892.2, IGKV2OR2-1, IGKV2OR2-2, IGKV1OR2-3, GPAT2P2, FAHD2B, AC018892.3, RN7SL313P, ANKRD36, AC159540.2, AC159540.1, IGKV1OR2-9, IGKV2OR2-10, IGKV2OR2-7D, IGKV3OR2-5, IGKV1OR2-6, IGKV2OR2-7, IGKV2OR2-8, IGKV1OR2-11, AC092683.1, AC092683.2, ANKRD36B, AC017099.1, AC017099.2, UBTFL6, COX5B, ACTR1B, C2orf92, RNU4-8P, ZAP70, TMEM131, HMGN1P36, RNU7-96P, VWA3B, ATP5F1BP1, AC092675.1, CNGA3, AC092675.2, INPP4A, COA5, UNC50.
- chr5:58,198–45,895,970, 710 genes, copy number 5–7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 13,054. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
